Somatic mutation profile of tumor specimen TCGA-EY-A5W2-01A (aliquot TCGA-EY-A5W2-01A-11D-A31U-09) from TCGA case TCGA-EY-A5W2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.5 years (26,498 days).
Specimen TCGA-EY-A5W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 477f51ba-c92c-4a90-9385-17376c2929f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A5W2-10A (Blood Derived Normal), aliquot TCGA-EY-A5W2-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b10b9f6-c4da-4b4d-b87c-171c3c12193d

The open-access MAF lists 943 somatic variants for this specimen: 737 protein-altering or splice-affecting, 192 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 449, Frame Shift Del 197, Silent 192, Frame Shift Ins 34, Nonsense Mutation 32, Splice Site 10, In Frame Del 8, RNA 7, Splice Region 5, 3'UTR 2, Intron 2, Nonstop Mutation 1.

Variants (750 of 943; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BCL11A | c.976dup p.L326Pfs*212 (on ENST00000335712 / NM_001365609.1; = p.L360Pfs*212 on NM_018014.4) | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs768799046; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.11653C>T p.R3885* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs756032160, COSV54218449, COSV99449428; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FRMPD4 | c.1851del p.C618Vfs*8 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs886038208; ClinVar: pathogenic; called by mutect2, varscan2
- HIVEP2 | c.6667C>T p.R2223* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs1562493608, COSV99176544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.586+2T>C p.X196_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as rs1135402791, COSV62201760; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886041602, COSV55847404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.195C>G p.Y65* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); catalogued as rs878853936, CM110159, CM1513010, COSV64291341, COSV64293906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 52/128 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110173, CM983501, COSV64288670, COSV64294671; called by muse, mutect2, varscan2
- RAD50 | c.541del p.S181Qfs*9 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs786201531; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC12A1 | c.1163del p.F388Sfs*40 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | catalogued as rs779588655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AARS2 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs918980694, COSV99771645; called by muse, mutect2
- ABCA7 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs1021101046, COSV99566817; called by muse, mutect2, varscan2
- ABCA7 | c.5879C>T p.A1960V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV99566819; called by muse, mutect2, varscan2
- ABCD1 | c.1963C>T p.L655F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99497975; called by muse, mutect2, varscan2
- ABCD2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100429869; called by muse, mutect2, varscan2
- ABTB2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100132272, COSV54396130; called by muse, mutect2, varscan2
- AC098582.1 | c.2554T>C p.C852R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV52020027, COSV99986132; called by muse, mutect2, varscan2
- ACE2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1292756480, COSV99383205; called by muse, mutect2, varscan2
- ACOX2 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100250332; called by muse, mutect2, varscan2
- ACTL6B | c.345C>A p.H115Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99355806; called by muse, mutect2, varscan2
- ADAM21 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs149756061, COSV50792703; called by muse, mutect2
- ADAM7 | c.1871T>C p.M624T | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99445330; called by muse, mutect2, varscan2
- ADAM9 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs1446802951, COSV101122293; called by muse, mutect2, varscan2
- ADAMTS2 | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284196; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4603G>A p.G1535R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.773); catalogued as COSV99721730; called by muse, mutect2, varscan2
- ADCY1 | c.2454+1G>A p.X818_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99813091; called by muse, mutect2, varscan2
- AGL | c.3046A>G p.T1016A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV99650209; called by muse, mutect2, varscan2
- AGO2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs1005112700, COSV99595899; called by muse, mutect2, varscan2
- AGRP | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99341406; called by muse, mutect2, varscan2
- AHNAK | c.10583G>A p.G3528D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99950134; called by muse, mutect2, varscan2
- AKAP1 | c.1013T>G p.L338W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100028309; called by muse, mutect2, varscan2
- AKAP12 | c.2083G>T p.G695W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV53585254, COSV99482926; called by muse, mutect2, varscan2
- AKNAD1 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769303364, COSV100645947; called by muse, mutect2, varscan2
- ALDH2 | c.864dup p.K289Efs*45 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs771889973; called by mutect2, varscan2
- ALDH8A1 | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.643); catalogued as COSV99665086; called by muse, mutect2, varscan2
- ALKBH1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53173774; called by muse, mutect2, varscan2
- ALPK1 | c.3063dup p.S1022Ifs*2 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | catalogued as rs1159828137; called by mutect2, varscan2
- ALPK2 | c.4762A>G p.R1588G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV100864922; called by muse, mutect2
- ALPK3 | c.1487G>A p.S496N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV51931474; called by muse, mutect2
- ALS2CL | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100015381; called by muse, mutect2, varscan2
- AMIGO3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1452024515, COSV100246786; called by muse, mutect2, varscan2
- AMOTL1 | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100504825; called by muse, mutect2, varscan2
- ANKRD10 | c.1120T>C p.Y374H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1231337491, COSV99941329; called by muse, mutect2, varscan2
- ANKRD17 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100430122; called by muse, mutect2, varscan2
- ANKRD35 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100841878; called by muse, mutect2, varscan2
- AP1B1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100434888; called by muse, mutect2, varscan2
- APOB | c.2369A>G p.H790R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1423482308, COSV99268652; called by muse, mutect2, varscan2
- AREG | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756509675; called by muse, mutect2, varscan2
- ARHGEF12 | c.3962A>G p.D1321G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100755288; called by muse, mutect2, varscan2
- ARHGEF4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756233817, COSV100388893; called by muse, mutect2, varscan2
- ARID1A | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV100253847; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as rs758608743; called by mutect2, varscan2
- ARSI | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs768458249, COSV100156158; called by muse, mutect2, varscan2
- ART1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1353528888, COSV99167280; called by muse, mutect2, varscan2
- ASIC2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1400296180, COSV99861345; called by muse, mutect2, varscan2
- ASPG | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV101496465; called by muse, mutect2, varscan2
- ATF7IP2 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100202863; called by muse, mutect2, varscan2
- ATG4C | c.681del p.A228Qfs*14 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV58605611; called by mutect2, pindel, varscan2
- ATM | c.1802G>T p.S601I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as CS031766, COSV53738889; called by muse, mutect2, varscan2
- ATP10A | c.2093C>G p.P698R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100791636; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP4A | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as COSV99383194; called by muse, mutect2, varscan2
- ATP8A1 | c.3058G>A p.V1020M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100047534; called by muse, mutect2, varscan2
- BACH1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs139083953, COSV54520511; called by muse, mutect2, varscan2
- BCL2L13 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs368311793; called by muse, mutect2, varscan2
- BDKRB2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021573; called by muse, mutect2, varscan2
- BMP4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV99817196; called by muse, mutect2, varscan2
- BMP5 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753026421, COSV100896425; called by muse, varscan2
- BPGM | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100790236; called by muse, mutect2, varscan2
- BRCA1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.87); catalogued as rs397508904, CM077917, COSV100525267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6460T>C p.Y2154H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV101204709; called by muse, mutect2
- BRCA2 | c.10192C>T p.Q3398* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1566261530, COSV58412101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD2 | c.1053A>C p.K351N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100875877; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs763134487; called by mutect2, varscan2
- BRIP1 | c.2825G>A p.C942Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.005); catalogued as rs370330739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100241746; called by muse, mutect2, varscan2
- C12orf4 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV99713010; called by muse, mutect2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C2CD2 | c.952T>G p.F318V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV100298484; called by muse, mutect2, varscan2
- C7 | c.2114G>A p.W705* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100496453; called by muse, mutect2, varscan2
- C7orf61 | c.571del p.R191Dfs*8 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs767078637; called by mutect2, pindel, varscan2
- CACNA2D4 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as rs766593449, COSV54947762; called by muse, mutect2
- CACNG7 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV55815510; called by muse, mutect2, varscan2
- CAD | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs779903352, COSV99255001, COSV99255345; called by muse, mutect2, varscan2
- CAPN2 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54339454, COSV99689363; called by muse, mutect2, varscan2
- CARMIL3 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs762097756, COSV57724435; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs770159446; called by mutect2, varscan2
- CCDC144A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.726); catalogued as COSV100502270; called by muse, mutect2, varscan2
- CCDC86 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs1276890787, COSV99920339; called by muse, mutect2, varscan2
- CCKAR | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99810614; called by muse, mutect2, varscan2
- CCL27 | c.71-2A>G p.X24_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99426616; called by muse, mutect2, varscan2
- CDCA7L | c.1215del p.C406Vfs*46 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV100181107; called by mutect2, pindel, varscan2
- CDH1 | c.521del p.N174Tfs*41 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as COSV55737132; called by mutect2, pindel, varscan2
- CDH19 | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100052550; called by muse, mutect2, varscan2
- CDS2 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100986198; called by muse, mutect2, varscan2
- CELF3 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753294142, COSV51885901; called by muse, mutect2, varscan2
- CEP170B | c.4338G>T p.Q1446H (on ENST00000453495; = p.Q1375H on NM_015005.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99229975; called by muse, mutect2, varscan2
- CEP350 | c.7582G>A p.G2528R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143908772; called by muse, mutect2, varscan2
- CEP76 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100043057; called by muse, mutect2, varscan2
- CETN3 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV99300676; called by muse, mutect2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP36 | c.109T>C p.C37R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100171189; called by muse, mutect2, varscan2
- CFAP54 | c.5290G>C p.V1764L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100732877; called by muse, mutect2, varscan2
- CFAP94 | c.1059A>G p.A353= (on ENST00000320267 / NM_001352064.2; = p.A359= on NM_018272.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100209826; called by muse, mutect2, varscan2
- CFHR5 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as rs370641856, COSV99889408; called by muse, mutect2, varscan2
- CHI3L1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs201313181, COSV55138265, COSV99704200; called by muse, mutect2
- CLCN2 | c.2068del p.E690Rfs*6 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs765672654; called by mutect2, pindel, varscan2
- CLCN4 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101074113; called by muse, mutect2, varscan2
- CLEC7A | c.553C>T p.R185W (on ENST00000304084 / NM_197947.3; = p.R139W on NM_022570.5) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53721984; called by muse, mutect2, varscan2
- CLIC1 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV101007571, COSV65383879; called by muse, mutect2, varscan2
- CLIC4 | c.612del p.K204Nfs*11 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1175213607; called by mutect2, pindel, varscan2
- CLPTM1L | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as rs973777399, COSV100307413; called by muse, mutect2, varscan2
- CLTCL1 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV99596049; called by muse, mutect2, varscan2
- CMTR1 | c.1944G>A p.E648= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV65089642; called by muse, mutect2, varscan2
- CNTLN | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs754809834, COSV52072643; called by muse, mutect2, varscan2
- CNTNAP1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.054); catalogued as rs1358716939, COSV99227181; called by muse, mutect2, varscan2
- CNTROB | c.2489A>G p.Y830C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV100972808; called by muse, mutect2, varscan2
- COL8A1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53735314; called by muse, mutect2, varscan2
- CPNE5 | c.1169del p.P390Rfs*11 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as COSV55199744; called by mutect2, pindel, varscan2
- CPPED1 | c.470del p.G157Afs*21 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs758254494; called by mutect2, pindel, varscan2
- CRACD | c.3311A>C p.Q1104P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99950178; called by muse, mutect2, varscan2
- CSMD1 | c.2386T>A p.S796T (on ENST00000520002; = p.S795T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.983); catalogued as COSV100154864; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTCF | c.143del p.G48Vfs*14 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as COSV50489849, COSV99864074; called by mutect2, pindel, varscan2
- CUEDC1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs768323459, COSV100804632; called by muse, mutect2, varscan2
- CUL7 | c.2063G>T p.R688I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99539410; called by muse, mutect2, varscan2
- CXorf66 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 58/129 reads (45%) | catalogued as COSV65169696; called by muse, mutect2, varscan2
- CYP2A6 | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99992238; called by muse, mutect2, varscan2
- CYP2E1 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99429299; called by muse, mutect2, varscan2
- CYSTM1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as rs1041378087, COSV99945129; called by muse, mutect2, varscan2
- DACH2 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100914085, COSV64171805; called by muse, mutect2, varscan2
- DCAF4 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs150886917, COSV62319720; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.11); catalogued as rs939581167, COSV101190759; called by muse, mutect2, varscan2
- DENND5B | c.2980C>T p.Q994* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100172399; called by muse, mutect2, varscan2
- DHX33 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99834550; called by muse, mutect2, varscan2
- DIDO1 | c.2573G>A p.G858D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV99827484; called by muse, mutect2, varscan2
- DIS3 | c.2698G>C p.V900L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100900030; called by muse, mutect2, varscan2
- DIS3L | c.579G>A p.W193* (on ENST00000319212 / NM_001143688.3; = p.W110* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100055690; called by muse, mutect2, varscan2
- DLG4 | c.569A>G p.Y190C (on ENST00000399506 / NM_001321075.3; = p.Y233C on NM_001365.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100264087; called by muse, mutect2, varscan2
- DNAH7 | c.10090C>T p.H3364Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100418127; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.4937T>C p.M1646T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV100547441; called by muse, mutect2, varscan2
- DNAI4 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs775900547, COSV64020705; called by muse, mutect2, varscan2
- DNAJB14 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1183142425, COSV100508655; called by muse, mutect2, varscan2
- DNMT3A | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs752434188, COSV53039335; called by muse, mutect2, varscan2
- DOCK2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748633577, COSV56948191; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK8 | c.5040G>T p.E1680D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV101210111; called by muse, mutect2, varscan2
- DPH6 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854084; called by muse, mutect2, varscan2
- DPYSL5 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99981881; called by muse, mutect2, varscan2
- DTNBP1 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100161279; called by muse, mutect2, varscan2
- DTX2 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100184908; called by muse, mutect2, varscan2
- DUS3L | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as COSV100288547; called by muse, mutect2, varscan2
- DUSP11 | c.143T>C p.M48T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731311; called by muse, mutect2
- DUSP9 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs782788434, COSV100720195; called by muse, mutect2, varscan2
- DYNC1I1 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV100269572; called by muse, mutect2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | catalogued as rs772082432; called by mutect2, varscan2
- EEF1AKMT4 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99955633; called by muse, mutect2, varscan2
- EEF2KMT | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs573199881, COSV101435316; called by muse, mutect2, varscan2
- EFCAB6 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.723); catalogued as rs139786740, COSV53059050; called by muse, mutect2, varscan2
- EFL1 | c.1574T>C p.L525S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99189190; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567del p.L856Wfs*7 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs35250897; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs748937918; called by mutect2, varscan2
- ELF1 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as rs1378908913, COSV53499805; called by muse, mutect2, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs961001512; called by mutect2, pindel, varscan2
- EPC2 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs758474126, COSV99310331; called by muse, mutect2, varscan2
- ERCC4 | c.2656A>G p.S886G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61314201; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV6 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs752454285, COSV101122803; called by muse, mutect2, varscan2
- EYA1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV100380477; called by muse, mutect2, varscan2
- FADS2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV99609219; called by muse, mutect2, varscan2
- FAM135A | c.2730A>G p.I910M (on ENST00000370479 / NM_001351599.1; = p.I697M on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV99526822; called by muse, mutect2, varscan2
- FAM47B | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV100264713; called by muse, mutect2, varscan2
- FASTKD1 | c.378G>A p.Q126= | Splice Region (SNP) | VAF 29/57 reads (51%) | catalogued as COSV101328551; called by muse, mutect2, varscan2
- FBN3 | c.4206C>A p.C1402* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99562047; called by muse, mutect2, varscan2
- FBRS | c.836G>A p.R279Q (on ENST00000287468; = p.R799Q on NM_001105079.3) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs780832620, COSV99789438; called by muse, mutect2, varscan2
- FBXW7 | c.1196A>T p.D399V (on ENST00000281708 / NM_001349798.2; = p.D319V on NM_018315.5) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661793; called by muse, mutect2, varscan2
- FDX2 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100593849; called by muse, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs144178676; called by mutect2, varscan2
- FILIP1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.134); catalogued as COSV99385653; called by muse, mutect2, varscan2
- FLAD1 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99421805; called by muse, mutect2, varscan2
- FLI1 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.376); catalogued as COSV100793953; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | catalogued as rs769482947; called by mutect2, varscan2
- FN1 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as rs770425267, COSV60554385; called by muse, mutect2, varscan2
- FN3K | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1341321921, COSV100333413; called by muse, mutect2, varscan2
- FOS | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1295646143, COSV100338661; called by muse, mutect2, varscan2
- FOXD4L5 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.425); catalogued as COSV101073308; called by muse, mutect2, varscan2
- FRAS1 | c.12037T>C p.*4013Qext*10 | Nonstop Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99356568; called by muse, mutect2, varscan2
- FRMD6 | c.572G>A p.R191K (on ENST00000344768 / NM_001267046.2; = p.R183K on NM_152330.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100656411; called by muse, mutect2, varscan2
- FRS3 | c.879dup p.L294Afs*30 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs768098936; called by mutect2, pindel, varscan2
- FRY | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs756972894, COSV100969787; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs1348158626; called by mutect2, varscan2
- FZD8 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65968487; called by muse, mutect2, varscan2
- GAK | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs749984140, COSV58509672; called by muse, mutect2, varscan2
- GALNS | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1401175486, CM970607, COSV99243541; called by muse, mutect2, varscan2
- GAS6 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs555163572, COSV100581463; called by muse, mutect2, varscan2
- GFI1B | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1430790946, COSV59744502; called by muse, mutect2, varscan2
- GLB1L2 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.989); catalogued as COSV100335543; called by muse, mutect2, varscan2
- GNAT1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV99138117; called by muse, mutect2, varscan2
- GNPAT | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199523352, COSV64153558; called by muse, mutect2, varscan2
- GOLGA2 | c.2713G>T p.G905W | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100360464; called by muse, mutect2, varscan2
- GPBP1L1 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as rs1381492223, COSV99322835; called by muse, mutect2, varscan2
- GPC4 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100895624; called by muse, mutect2, varscan2
- GPR137 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs149311005; called by muse, mutect2, varscan2
- GPR182 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as COSV100267820; called by muse, mutect2
- GPR6 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99254629; called by muse, mutect2
- GPRIN2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs782738328, COSV65401181; called by muse, mutect2, varscan2
- GPS1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136176; called by muse, mutect2, varscan2
- GREB1 | c.5428G>A p.A1810T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1201937282, COSV52188141; called by muse, mutect2, varscan2
- GSDME | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100742472, COSV61652739; called by muse, mutect2, varscan2
- GSE1 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV99497342; called by muse, mutect2, varscan2
- GTF2F2 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100477566; called by muse, mutect2, varscan2
- GTF2H3 | c.562-1G>T p.X188_splice | Splice Site (SNP) | VAF 29/58 reads (50%) | catalogued as COSV99967519; called by muse, mutect2, varscan2
- GUCY1A2 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as COSV99977512; called by muse, mutect2, varscan2
- H2AC14 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100297698; called by muse, mutect2, varscan2
- HAAO | c.599T>A p.L200H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV99685608; called by muse, mutect2, varscan2
- HCAR1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs757909237, COSV63671357; called by muse, mutect2, varscan2
- HCFC1 | c.5103G>T p.Q1701H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV100128445, COSV100130145, COSV60072675; called by muse, mutect2, varscan2
- HDAC6 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs782213675, COSV100491355, COSV99043233; called by muse, mutect2, varscan2
- HERC1 | c.4380A>G p.I1460M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV101497070; called by muse, mutect2, varscan2
- HERC2 | c.9746A>G p.Q3249R | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV99877523; called by muse, mutect2, varscan2
- HHLA2 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as rs371642037; called by muse, mutect2, varscan2
- HIC1 | c.1418C>T p.A473V (on ENST00000322941 / NM_001098202.1; = p.A454V on NM_006497.4) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs1316079632, COSV99558918; called by muse, mutect2, varscan2
- HIF3A | c.499C>T p.R167C (on ENST00000377670 / NM_152795.4; = p.R98C on NM_022462.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371476587; called by muse, mutect2, varscan2
- HJV | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs782713967, COSV100382439; called by muse, mutect2
- HMCN1 | c.6748G>A p.G2250R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99637440; called by muse, mutect2
- HNRNPA2B1 | c.56A>G p.Q19R (on ENST00000354667 / NM_031243.3; = p.Q7R on NM_002137.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV100523036; called by muse, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs767148651; called by mutect2, varscan2
- HSD3B1 | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs751833543, COSV99348147; called by muse, varscan2
- HSP90AB1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV99241503; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- HSPB1 | c.438del p.G147Vfs*17 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs747325717; called by mutect2, pindel, varscan2
- IFT57 | c.466T>A p.L156M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99198301; called by muse, mutect2, varscan2
- IK | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as rs199572934, COSV100845612; called by muse, mutect2, varscan2
- IL17RA | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100083522; called by muse, mutect2, varscan2
- IL27RA | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV99652489; called by muse, mutect2, varscan2
- IL4I1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1485335203, COSV99680994; called by muse, mutect2, varscan2
- ING1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58166474; called by muse, mutect2, varscan2
- INKA2 | c.559dup p.A187Gfs*3 | Frame Shift Ins (INS) | VAF 12/25 reads (48%) | catalogued as rs751997684; called by mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IRS4 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs112652908, COSV100929823; called by muse, mutect2, varscan2
- IRX4 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs750340725, COSV99182719; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- IVD | c.581G>A p.G194D (on ENST00000651168; = p.G191D on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991644; called by muse, mutect2, varscan2
- JAKMIP2 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV99509458; called by muse, mutect2, varscan2
- KANSL1 | c.3121del p.L1041Wfs*71 (on ENST00000574590 / NM_001193465.2; = p.L1042Wfs*71 on NM_015443.4) | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs1417809123; called by mutect2, pindel, varscan2
- KCNH4 | c.2397del p.R800Gfs*28 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs778022334; called by mutect2, pindel
- KCNQ5 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100573375; called by muse, mutect2, varscan2
- KCTD5 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV100069763; called by muse, mutect2, varscan2
- KEL | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100787348; called by muse, mutect2, varscan2
- KIF18B | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs978990055, COSV100192572, COSV100192699; called by muse, mutect2, varscan2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV52136659; called by mutect2, pindel, varscan2
- KIF7 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs143915145, CM1511082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIT | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855583; called by muse, mutect2, varscan2
- KLF17 | c.465del p.N156Mfs*13 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs1384429599; called by mutect2, pindel, varscan2
- KLHL15 | c.1330T>A p.C444S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.221); catalogued as COSV100044488; called by muse, mutect2
- KMT2A | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV63281797; called by muse, mutect2, varscan2
- KNOP1 | c.957dup p.G320Rfs*5 | Frame Shift Ins (INS) | VAF 67/150 reads (45%) | catalogued as rs759734033; called by mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs764099275; called by mutect2, varscan2
- KRAS | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs758575947, COSV55724297; called by muse, mutect2
- KRT3 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100527374; called by muse, mutect2, varscan2
- KRT71 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99922448; called by muse, mutect2
- KRTAP10-11 | c.90dup p.C31Lfs*33 | Frame Shift Ins (INS) | VAF 42/97 reads (43%) | catalogued as rs1555939780; called by mutect2, pindel, varscan2
- KRTAP3-2 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV101196054; called by muse, mutect2, varscan2
- LACRT | c.379T>A p.L127I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.968); catalogued as COSV99143835, COSV99143934; called by muse, mutect2, varscan2
- LAMA5 | c.10427G>A p.S3476N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV99442853; called by muse, mutect2, varscan2
- LAMB2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100565567; called by muse, mutect2, varscan2
- LCE1C | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.654); catalogued as rs534849272, COSV64218993; called by muse, mutect2, varscan2
- LDLRAD3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs368201136, COSV100215431; called by mutect2, varscan2
- LEXM | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs747029211, COSV64023292; called by muse, mutect2, varscan2
- LIG3 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1459305342, COSV99253289; called by muse, mutect2, varscan2
- LILRA2 | c.872del p.G291Afs*25 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | catalogued as COSV52194613; called by mutect2, pindel, varscan2
- LIPF | c.531T>C p.I177= | Splice Region (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99490676; called by muse, mutect2, varscan2
- LNX1 | c.1478C>T p.T493I (on ENST00000263925 / NM_001126328.3; = p.T397I on NM_032622.2) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as rs1444719752, COSV99820737; called by muse, varscan2
- LPCAT2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV99528375; called by muse, varscan2
- LPCAT3 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54647856; called by muse, mutect2, varscan2
- LRIG1 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1414851888, COSV99834589; called by muse, mutect2
- LRP1 | c.9472T>C p.Y3158H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99677715; called by muse, mutect2, varscan2
- LRP10 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.76); catalogued as COSV100612536; called by muse, mutect2
- LTA4H | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99957363; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs754757253, COSV52588935; called by mutect2, varscan2
- LYST | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV67715319; called by muse, mutect2, varscan2
- MACC1 | c.2295G>A p.M765I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100256379; called by muse, mutect2, varscan2
- MAGEB2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750718375, COSV66780282; called by muse, mutect2, varscan2
- MAN2B1 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1446398033, COSV99666804, COSV99667440; called by muse, mutect2, varscan2
- MAP2 | c.5399C>T p.S1800F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99562065; called by muse, mutect2, varscan2
- MASP1 | c.744+2T>C p.X248_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99397788; called by muse, mutect2, varscan2
- MAST2 | c.4553C>T p.A1518V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1380119327, COSV53106951; called by muse, mutect2
- MAT1A | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100944504; called by muse, mutect2, varscan2
- MCF2L2 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100194209; called by muse, mutect2, varscan2
- MCM7 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100385011, COSV57994532; called by muse, mutect2, varscan2
- MDGA1 | c.2230A>G p.N744D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1412905393, COSV99777500; called by muse, mutect2, varscan2
- MED16 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.96); catalogued as COSV99516428; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MFSD1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 26/46 reads (57%) | catalogued as rs747509407, COSV99964150; called by muse, mutect2, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MGAT5B | c.191del p.G64Afs*11 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs963709095, COSV100047240; called by mutect2, pindel, varscan2
- MICAL3 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs368124560; called by muse, mutect2, varscan2
- MMEL1 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99983318; called by muse, mutect2, varscan2
- MON2 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1378968241, COSV99743935; called by muse, mutect2, varscan2
- MPL | c.1192T>C p.W398R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.503); catalogued as COSV100991815; called by muse, mutect2, varscan2
- MPP3 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV101263374; called by muse, mutect2
- MROH5 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101436195; called by muse, mutect2
- MSH4 | c.58_60del p.S20del | In Frame Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1471035837; called by pindel, varscan2
- MYBPC1 | c.3223A>G p.K1075E (on ENST00000550270 / NM_206820.2; = p.K1082E on NM_002465.4) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100638333; called by muse, mutect2, varscan2
- MYL10 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766324773, COSV99781241; called by muse, mutect2, varscan2
- MYO15A | c.9690+1G>A p.X3230_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as CS154772, COSV99234849; called by muse, mutect2, varscan2
- MYO1C | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as COSV100704601; called by muse, mutect2, varscan2
- MYOM1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1001422774, COSV99868820; called by muse, mutect2
- MYOM3 | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs752339341, COSV100142025, COSV58398239; called by muse, mutect2, varscan2
- MYOZ1 | c.287dup p.Q97Tfs*34 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | catalogued as rs768785792; called by mutect2, varscan2
- NAA35 | c.2003T>C p.M668T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100863472; called by muse, mutect2, varscan2
- NAB1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1053176, COSV61609598; called by muse, mutect2, varscan2
- NAV3 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99896707; called by muse, mutect2, varscan2
- NBAS | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99872071; called by muse, mutect2, varscan2
- NBEAL1 | c.6268A>G p.I2090V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.083); catalogued as rs375685765; called by muse, mutect2, varscan2
- NBN | c.2033A>G p.D678G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99620257; called by mutect2, varscan2
- NBR1 | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV100358037; called by muse, mutect2, varscan2
- NCAPD3 | c.2195T>G p.L732R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV101599407; called by muse, mutect2, varscan2
- NCF1 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs2523331, COSV99194339; called by muse, mutect2, varscan2
- NCOR2 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1367743519, COSV100658009, COSV62292655; called by muse, mutect2, varscan2
- NDUFAF7 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.617); catalogued as COSV99135860; called by muse, mutect2, varscan2
- NDUFS4 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692521; called by muse, mutect2, varscan2
- NELL1 | c.1450C>A p.Q484K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100125937; called by muse, mutect2, varscan2
- NHSL2 | c.962C>T p.P321L (on ENST00000510661; = p.P687L on NM_001013627.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101030407; called by muse, mutect2
- NIBAN3 | c.1586G>A p.G529D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV99962834; called by muse, mutect2, varscan2
- NKX2-3 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV100755139; called by muse, mutect2, varscan2
- NLRP11 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100789817, COSV100789833; called by muse, mutect2, varscan2
- NLRP12 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV100146060; called by muse, mutect2, varscan2
- NOP2 | c.2331del p.K778Rfs*? (on ENST00000322166 / NM_001258308.2; = p.K774Rfs*? on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as COSV59113000; called by mutect2, pindel, varscan2
- NR1H4 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.11); catalogued as COSV99501324; called by muse, mutect2, varscan2
- NR4A2 | c.247_248insA p.L83Hfs*9 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | catalogued as COSV100277455; called by mutect2, pindel, varscan2
- NR4A3 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100432838; called by muse, mutect2, varscan2
- NTM | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100869851; called by muse, mutect2, varscan2
- NUFIP1 | c.276del p.F93Sfs*110 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1312316556, COSV63151730; called by mutect2, pindel, varscan2
- OBSCN | c.12260T>G p.L4087R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485771; called by muse, mutect2, varscan2
- OBSCN | c.22829G>A p.C7610Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100806398, COSV62423530; called by muse, varscan2
- OR10G2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101606975; called by muse, mutect2, varscan2
- OR1E2 | c.761T>G p.L254R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99943529; called by muse, mutect2, varscan2
- OR2L2 | c.530dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 53/173 reads (31%) | catalogued as rs1490247970; called by mutect2, pindel, varscan2
- OR2T1 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100822365, COSV63541383; called by muse, mutect2, varscan2
- OR52W1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100258770; called by muse, mutect2, varscan2
- OR5B12 | c.597dup p.V200Cfs*6 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5D13 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1250440824, COSV100687115; called by muse, mutect2, varscan2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR9G1 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100380426; called by muse, mutect2
- OSBPL7 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1277565837, COSV50106488; called by muse, mutect2, varscan2
- OTUD7A | c.1546C>T p.R516C (on ENST00000307050 / NM_001382637.1; = p.R509C on NM_130901.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747699554, COSV61035874; called by muse, mutect2, varscan2
- OXCT1 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778813276, COSV52168828; called by muse, mutect2, varscan2
- P2RY2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs751836374, COSV60776807; called by muse, varscan2
- PADI6 | c.1945T>C p.C649R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100640049; called by muse, mutect2, varscan2
- PAF1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.029); catalogued as COSV99656108; called by muse, mutect2, varscan2
- PAK1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV99584078; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs758945932; called by mutect2, varscan2
- PATJ | c.2963T>C p.M988T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100335229; called by muse, mutect2, varscan2
- PAX1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV68271968; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PC | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs138618426; called by muse, mutect2, varscan2
- PCDH17 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100931388, COSV100931775; called by muse, mutect2, varscan2
- PCDH7 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100688747; called by muse, mutect2, varscan2
- PCDHB11 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV100697213; called by muse, varscan2
- PCDHB11 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as COSV100697214, COSV61312960; called by muse, mutect2, varscan2
- PCDHB4 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.179); catalogued as COSV52020239, COSV99522329; called by muse, mutect2, varscan2
- PCNT | c.6410del p.G2137Vfs*2 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as COSV64032914; called by mutect2, pindel, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs768249210; called by mutect2, varscan2
- PDE9A | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750539213, COSV99372402; called by muse, mutect2, varscan2
- PDZD9 | c.500A>G p.Y167C (on ENST00000424898 / NM_001363519.1; = p.Y107C on NM_173806.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV99193413; called by muse, mutect2
- PER2 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV99612733; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF2 | c.2995G>A p.A999T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.133); catalogued as COSV63679038; called by muse, mutect2, varscan2
- PHF20 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100926769; called by muse, mutect2, varscan2
- PHLPP1 | c.3872G>A p.C1291Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409553; called by muse, mutect2, varscan2
- PIF1 | c.1867-1G>A p.X623_splice | Splice Site (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99165411; called by muse, mutect2, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | catalogued as COSV63249731; called by pindel, varscan2
- PKD2L1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100559476; called by muse, mutect2, varscan2
- PKP3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100520980; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCD3 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100504480; called by muse, mutect2
- PLCE1 | c.1161A>G p.I387M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1028504203, COSV99597707; called by muse, mutect2, varscan2
- PLD3 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99396211; called by muse, mutect2, varscan2
- PLEKHG6 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746629523, COSV99164170, COSV99165157; called by muse, mutect2, varscan2
- PLEKHM3 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101216974; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs765091847; called by mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNA4 | c.1709T>C p.V570A | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as rs1224985085, COSV100327886; called by muse, mutect2, varscan2
- PLXNB1 | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs771028218, COSV99603598; called by muse, mutect2, varscan2
- PLXNB2 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs375577050; called by muse, mutect2, varscan2
- PM20D1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs199717760, COSV65648532; called by muse, mutect2, varscan2
- PNPLA7 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs375690090; called by muse, mutect2, varscan2
- POMT1 | c.230-2A>G p.X77_splice | Splice Site (SNP) | VAF 49/126 reads (39%) | catalogued as COSV100586625; called by muse, mutect2, varscan2
- PPARG | c.649G>A p.E217K (on ENST00000287820 / NM_015869.5; = p.E187K on NM_005037.7) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs766913119, CM1412195, COSV99826874; called by muse, mutect2, varscan2
- PPIAL4G | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.21); catalogued as rs1222935760, COSV101344038; called by muse, mutect2, varscan2
- PPM1K | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs369230362; called by muse, mutect2
- PPP1R15B | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100916385; called by muse, mutect2
- PPP1R9B | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100380818; called by muse, mutect2, varscan2
- PPP6R1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101337021; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as COSV53386648; called by mutect2, pindel, varscan2
- PQBP1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99504631; called by muse, mutect2, varscan2
- PRDM1 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100959034; called by muse, mutect2, varscan2
- PRDM16 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99579393; called by muse, mutect2, varscan2
- PRICKLE2 | c.2194C>T p.R732C (on ENST00000295902; = p.R676C on NM_198859.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as COSV55766075; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as rs537061158; called by mutect2, varscan2
- PROM2 | c.2486T>C p.V829A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100469478; called by muse, mutect2, varscan2
- PRPSAP2 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99264783; called by muse, mutect2, varscan2
- PSKH2 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99405448; called by muse, mutect2, varscan2
- PSMD12 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100635454; called by muse, mutect2, varscan2
- PSMD2 | c.2398C>T p.L800F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100032053; called by muse, mutect2, varscan2
- PTGS1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs200993905, COSV56292183; called by muse, mutect2, varscan2
- PTK6 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as rs1429070092, COSV99420934; called by muse, mutect2, varscan2
- PTPN13 | c.855dup p.P286Tfs*6 | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPN4 | c.2062A>T p.I688F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99751669; called by muse, varscan2
- PWWP3B | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs373158939, COSV61799340; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs755727862; called by mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 52/119 reads (44%) | catalogued as rs754588466; called by mutect2, varscan2
- RAD54B | c.1774_1775del p.C592Qfs*16 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs1189353686; called by pindel, varscan2
- RAI14 | c.816del p.K272Nfs*14 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as COSV54298149; called by mutect2, pindel, varscan2
- RAI14 | c.2556_2558del p.L853del | In Frame Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs1300560858; called by mutect2, varscan2
- RALA | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV99143335; called by muse, mutect2, varscan2
- RANBP1 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs756772977, COSV100082411; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RARA | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs1457382271, COSV54189833; called by muse, mutect2, varscan2
- RASAL3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1238820200, COSV59139312; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as COSV60328025; called by mutect2, pindel, varscan2
- RBMX2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1303668391, COSV100564731, COSV100564890; called by muse, mutect2, varscan2
- RC3H2 | c.2911A>G p.I971V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV100606179; called by muse, mutect2
- RELA | c.1606_1608del p.S536del | In Frame Del (DEL) | VAF 13/25 reads (52%) | catalogued as rs766441250; called by pindel, varscan2
- REM2 | c.415G>T p.G139* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV99944795; called by muse, mutect2, varscan2
- REXO2 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV99771825; called by muse, mutect2, varscan2
- RFWD3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.115); catalogued as rs1243493131, COSV100736335; called by muse, mutect2, varscan2
- RFX7 | c.1415T>G p.L472W (on ENST00000559447 / NM_001368074.1; = p.L569W on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100429545; called by muse, mutect2, varscan2
- RIMKLA | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101343495; called by muse, mutect2, varscan2
- RIPK4 | c.1789C>T p.Q597* (on ENST00000352483; = p.Q549* on NM_020639.3) | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV60186797; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs1192824348; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL36AL | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100023318; called by muse, mutect2, varscan2
- RPL36AL | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs1254906937, COSV100023319; called by muse, mutect2, varscan2
- RPS4X | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100289191, COSV60181462; called by muse, mutect2, varscan2
- RPS6KC1 | c.1837C>A p.L613M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100874136; called by muse, mutect2, varscan2
- RPTN | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100285885; called by muse, mutect2, varscan2
- RTRAF | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV99911059; called by muse, mutect2, varscan2
- RWDD4 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100419191; called by muse, mutect2, varscan2
- RYR2 | c.12687G>T p.Q4229H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100773278; called by muse, mutect2, varscan2
- SBF1 | c.2900T>C p.I967T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100818104; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as COSV54589079; called by mutect2, varscan2
- SCN4A | c.3190A>G p.I1064V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs755509972, COSV101438710; called by muse, mutect2, varscan2
- SCN5A | c.4631C>T p.T1544I (on ENST00000333535 / NM_198056.3; = p.T1543I on NM_000335.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV100351195; called by muse, mutect2, varscan2
- SEC24B | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99494505; called by muse, mutect2, varscan2
- SEMA4A | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.329); catalogued as COSV100740759; called by muse, mutect2, varscan2
- SERPINB4 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100346054; called by muse, mutect2, varscan2
- SH3RF3 | c.1193G>T p.R398M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100514023; called by muse, mutect2, varscan2
- SH3TC2 | c.3619C>A p.L1207M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.365); catalogued as COSV100102499; called by muse, mutect2, varscan2
- SH3TC2 | c.1802G>A p.C601Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100102503; called by muse, mutect2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHH | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99793627; called by muse, mutect2, varscan2
- SHROOM2 | c.3287C>T p.T1096M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs866725835, COSV66605221; called by muse, mutect2, varscan2
- SIGLEC11 | c.1193del p.P398Qfs*4 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs774799128; called by mutect2, pindel, varscan2
- SIPA1L2 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV53395204; called by muse, mutect2, varscan2
- SIRPB1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV99498659; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A5 | c.1198G>A p.V400M (on ENST00000454036 / NM_001134771.2; = p.V377M on NM_020708.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99069308, COSV99717062; called by muse, mutect2, varscan2
- SLC13A4 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs148837419; called by muse, mutect2, varscan2
- SLC1A5 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101314842; called by mutect2, varscan2
- SLC22A23 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200011775, COSV100978456; called by mutect2, varscan2
- SLC22A23 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1240153588, COSV100978458, COSV104430999; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC23A1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100812128; called by muse, mutect2, varscan2
- SLC25A41 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199918673, COSV100383179; called by muse, mutect2, varscan2
- SLC26A1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs558027930, COSV56104355; called by muse, mutect2
- SLC2A6 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782337112, COSV52471981; called by muse, mutect2, varscan2
- SLC35C2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.485); catalogued as rs768551340, COSV54758972; called by muse, mutect2, varscan2
- SLC36A1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695827; called by mutect2, varscan2
- SLC45A3 | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100901373; called by muse, mutect2, varscan2
- SLC47A2 | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100328345; called by muse, mutect2, varscan2
- SLC6A6 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1391469650, COSV62649119; called by muse, mutect2, varscan2
- SLC9A3R2 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526557; called by muse, mutect2, varscan2
- SLC9A7 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60378341; called by muse, mutect2, varscan2
- SLCO3A1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs758860169, COSV100575951; called by muse, mutect2, varscan2
- SLIT3 | c.3338del p.P1113Hfs*108 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs1319942034; called by mutect2, pindel, varscan2
- SLX4 | c.2441A>G p.N814S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs777299783, COSV99568797; called by muse, mutect2, varscan2
- SMC1B | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs761499778, COSV100663596; called by muse, mutect2, varscan2
- SMG6 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99558920; called by muse, mutect2
- SMS | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV101048323; called by muse, mutect2, varscan2
- SOX17 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810843; called by muse, mutect2, varscan2
- SOX6 | c.1651C>T p.P551S (on ENST00000528429 / NM_001145819.2; = p.P524S on NM_017508.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57046594; called by muse, mutect2, varscan2
- SPACA9 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100052724; called by muse, mutect2, varscan2
- SPAG11B | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99873314; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs766867338, COSV56665809; called by muse, mutect2, varscan2
- SPHKAP | c.4885C>T p.Q1629* (on ENST00000392056 / NM_001142644.2; = p.Q1600* on NM_030623.3) | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100764637; called by muse, mutect2, varscan2
- SRP68 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV100326308; called by muse, mutect2, varscan2
- SRP72 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV100714400; called by muse, mutect2, varscan2
- SRSF6 | c.488T>C p.L163S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1295032438, COSV99719877; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs1563701552; called by mutect2, varscan2
- STK4 | c.36-1G>T p.X12_splice | Splice Site (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100860525; called by muse, mutect2, varscan2
- STX11 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100845544; called by muse, mutect2, varscan2
- STYXL2 | c.1844A>G p.E615G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1333562761, COSV99610042; called by muse, mutect2, varscan2
- SUFU | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100883218; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs747003550; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNCRIP | c.1788A>C p.Q596H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.948); catalogued as COSV100784365; called by muse, mutect2, varscan2
- SYT12 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs752980441, COSV67355412; called by muse, mutect2, varscan2
- TACC3 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs759970838, COSV100305156; called by muse, mutect2, varscan2
- TAF1 | c.4240G>A p.V1414M (on ENST00000373790 / NM_138923.4; = p.V1435M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs751029527, COSV52112044; called by muse, mutect2, varscan2
- TAF8 | c.683_685del p.L228del | In Frame Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs746056203; called by pindel, varscan2
- TAS2R30 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV101115888; called by muse, mutect2, varscan2
- TBC1D2 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59788576; called by muse, mutect2, varscan2
- TBC1D31 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); catalogued as rs1271522641, COSV99783322; called by muse, mutect2, varscan2
- TBC1D9B | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100783691; called by muse, mutect2, varscan2
- TBX2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99539214; called by muse, mutect2
- TCAP | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.185); catalogued as rs1242113080, COSV99510844; called by muse, mutect2, varscan2
- TCEAL5 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1411118534, COSV101013203; called by muse, mutect2, varscan2
- TCERG1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99695402; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs758822980; called by mutect2, varscan2
- TCP11L2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257767813, COSV100135590; called by mutect2, varscan2
- TENM3 | c.3850A>G p.M1284V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101305551; called by muse, mutect2, varscan2
- TENM4 | c.3361A>G p.T1121A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1251538156, COSV99580567; called by muse, mutect2, varscan2
- TERB2 | c.420del p.E141Nfs*11 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs768411130; called by mutect2, pindel, varscan2
- TET1 | c.65dup p.K23Efs*37 | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | catalogued as rs1196853334; called by mutect2, varscan2
- TFDP1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100945696, COSV100946063; called by muse, mutect2, varscan2
- TG | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs757630170, COSV99602867, COSV99603839; called by muse, mutect2, varscan2
- THOC5 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1282557849, COSV100803669; called by muse, mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs1443424346; called by mutect2, pindel, varscan2
- THSD7A | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV101448956; called by muse, mutect2, varscan2
- TIAM1 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.236); catalogued as COSV99739685; called by muse, mutect2, varscan2
- TIMELESS | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.514); catalogued as rs1329935174, COSV99974440; called by muse, mutect2, varscan2
- TLR4 | c.1697A>G p.H566R (on ENST00000355622 / NM_138554.5; = p.H526R on NM_003266.4) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100842905, COSV62922743; called by muse, mutect2, varscan2
- TLX2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752562250, COSV52046461; called by muse, mutect2, varscan2
- TMEM130 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100229061; called by muse, mutect2, varscan2
- TMEM50A | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1160076827, COSV100975967; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TOX4 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99398715; called by muse, mutect2, varscan2
- TP53BP2 | c.616G>A p.V206M (on ENST00000343537 / NM_001031685.3; = p.V77M on NM_005426.2) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336327761, COSV100636830; called by muse, mutect2, varscan2
- TPD52L1 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100509529; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM72 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as rs201191466, COSV57252191; called by muse, mutect2, varscan2
- TRIML2 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.891); catalogued as COSV100456425; called by muse, mutect2, varscan2
- TRIO | c.5845del p.L1949Ffs*19 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | catalogued as COSV60095341; called by mutect2, pindel, varscan2
- TRIOBP | c.6116G>T p.R2039L (on ENST00000644935 / NM_001039141.3; = p.R326L on NM_007032.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100462397; called by muse, mutect2, varscan2
- TRPC4AP | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.328); catalogued as rs775172026, COSV99329027; called by muse, mutect2, varscan2
- TSR2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100911283; called by muse, mutect2, varscan2
- TTBK1 | c.1316dup p.D440Rfs*19 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs757606010; called by mutect2, varscan2
- TTC39B | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896347; called by muse, mutect2, varscan2
- TTLL7 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553456; called by muse, mutect2, varscan2
- TTN | c.6244G>A p.E2082K (on ENST00000591111; = p.E2036K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | PolyPhen probably damaging (0.994); catalogued as rs750064248, COSV60146579; called by muse, mutect2, varscan2
- TUBB2B | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV99455751; called by muse, mutect2
- TUT4 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 49/93 reads (53%) | catalogued as COSV99932960; called by muse, mutect2, varscan2
- UBA6 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451997; called by muse, mutect2, varscan2
- UBAP2 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV100672060; called by muse, mutect2, varscan2
- UBE2M | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV99285506; called by muse, mutect2, varscan2
- UGGT1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99391317; called by muse, mutect2, varscan2
- UMODL1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368019684; called by muse, mutect2, varscan2
- UMODL1 | c.3332A>G p.N1111S (on ENST00000408910 / NM_001004416.2; = p.N1239S on NM_173568.3) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV101252762; called by muse, mutect2, varscan2
- USH2A | c.7540A>G p.N2514D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100244007, COSV100244096; called by muse, mutect2, varscan2
- USP1 | c.1985del p.N662Mfs*2 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs751218576; ClinVar: not provided; called by mutect2, varscan2
- USP13 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV99831880; called by muse, mutect2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP4 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as COSV55541047; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs762976381; called by mutect2, varscan2
- VIL1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV99945934; called by muse, mutect2, varscan2
- VILL | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754484560, COSV99379358; called by muse, mutect2, varscan2
- VPS41 | c.1163dup p.N388Kfs*3 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs757692785; called by mutect2, varscan2
- VWA1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs768572549, COSV100100833; called by muse, mutect2, varscan2
- WDR5B | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99216528; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIPI2 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99993665; called by muse, mutect2, varscan2
- XKR5 | c.108del p.W37Gfs*16 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs1473896170; called by mutect2, pindel, varscan2
- ZBED4 | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV99351845; called by muse, mutect2
- ZBED8 | c.404del p.K135Sfs*11 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs1189856243; called by mutect2, pindel, varscan2
- ZBED9 | c.2794T>A p.F932I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as COSV101509426, COSV71729236; called by muse, mutect2, varscan2
- ZBTB18 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62397137, COSV99080953; called by muse, mutect2
- ZBTB45 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.317); catalogued as rs1328626010, COSV63523530; called by muse, mutect2, varscan2
- ZBTB46 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV55507716; called by muse, mutect2
- ZBTB7B | c.938A>G p.D313G (on ENST00000292176; = p.D347G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.208); catalogued as COSV99421682; called by muse, mutect2, varscan2
- ZC3H4 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV53411076, COSV99452964; called by muse, mutect2
- ZCWPW1 | c.1878del p.Q627Rfs*? | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV52202246; called by mutect2, pindel, varscan2
- ZCWPW2 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.181); catalogued as rs533972511, COSV67497565; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs563751025; called by mutect2, varscan2
- ZKSCAN8 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562088137, COSV57637237; called by muse, mutect2
- ZMAT3 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100265432; called by muse, mutect2, varscan2
- ZMYM2 | c.2692C>T p.H898Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV101244185; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF141 | c.1162del p.I388Ffs*51 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | catalogued as rs782618581; called by mutect2, pindel, varscan2
- ZNF235 | c.2182T>C p.Y728H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.77); catalogued as COSV99349798; called by muse, mutect2, varscan2
- ZNF275 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100936349, COSV100936487; called by muse, mutect2, varscan2
- ZNF414 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99726734; called by muse, mutect2, varscan2
- ZNF502 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV99939897; called by muse, mutect2, varscan2
- ZNF513 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs988712484, COSV99278119; called by muse, mutect2, varscan2
- ZNF555 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.153); catalogued as rs763224777, COSV62073867; called by muse, mutect2, varscan2
- ZNF628 | c.1691G>T p.R564M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99220351; called by muse, mutect2, varscan2
- ZNF638 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100040283; called by muse, mutect2, varscan2
- ZNF668 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.163); catalogued as rs1363119018, COSV100337000; called by muse, mutect2, varscan2
- ZNF74 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100677599; called by muse, mutect2, varscan2
- ZNF74 | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); catalogued as rs201293900, COSV100677600; called by muse, mutect2, varscan2
- ZNF786 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100303054; called by muse, mutect2, varscan2
- ZNF804A | c.3098C>A p.A1033E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100170681; called by muse, mutect2, varscan2
- ZNF804B | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs373831275, COSV60821352; called by muse, mutect2
- ZNF813 | c.602T>C p.L201S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV101125030; called by muse, mutect2, varscan2
- ZNF835 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs1490177901, COSV101606268, COSV73379314; called by muse, mutect2, varscan2
- ZNF862 | c.1790C>T p.T597M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs373814141; called by muse, mutect2, varscan2
- ZSWIM8 | c.4802G>A p.S1601N (on ENST00000605216 / NM_001242487.2; = p.S1606N on NM_015037.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1288837118, COSV100014436; called by muse, mutect2, varscan2
- ZW10 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV99562992; called by muse, mutect2, varscan2
- ADCY9 | c.470_471dup p.G158Wfs*30 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- ADNP | c.1311del p.G438Vfs*40 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- ADNP | c.1310del p.P437Qfs*41 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2*, pindel, varscan2*
- ALMS1 | c.9585dup p.L3196Ifs*4 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- AOC1 | c.568del p.R190Gfs*18 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- AR | c.1440del p.Y481Tfs*29 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- ARHGAP22 | c.2044del p.S682Rfs*3 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.3053dup p.Q1019Sfs*31 (on ENST00000310343 / NM_001378025.1; = p.Q670Sfs*31 on NM_014715.4) | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.2834del p.K945Rfs*3 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- ARID1A | c.4130_4131del p.Y1377Wfs*67 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by pindel, varscan2
- ARMT1 | c.949dup p.A317Gfs*2 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- ARSF | c.1511del p.P504Lfs*16 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ATF1 | c.605_606del p.L202Hfs*6 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- BTN3A2 | c.520del p.Q174Nfs*31 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- CARMIL1 | c.2388del p.A797Pfs*7 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- CCDC191 | c.907del p.M303Wfs*2 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- CCDC25 | c.480del p.A161Pfs*6 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1147del p.R383Afs*51 | Frame Shift Del (DEL) | VAF 50/114 reads (44%) | called by mutect2, varscan2
- CELSR2 | c.6048del p.W2017Gfs*17 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, varscan2
- CIR1 | c.1300del p.M434Cfs*13 | Frame Shift Del (DEL) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | called by mutect2, pindel, varscan2
- CPNE6 | c.243dup p.E82* | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, varscan2
- CUL4B | c.2199dup p.A734Sfs*4 | Frame Shift Ins (INS) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- CYTH3 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLG5 | c.2583dup p.G862Rfs*9 | Frame Shift Ins (INS) | VAF 29/72 reads (40%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- EDRF1 | c.399_401del p.L134del | In Frame Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- EGR2 | c.779del p.P260Lfs*21 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 39/69 reads (57%) | called by mutect2, pindel, varscan2
- FAM122A | c.715_716dup p.S240Yfs*43 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- FAM83E | c.889del p.Q297Rfs*6 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- FANCM | c.2604del p.E869Kfs*7 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.263del p.N88Mfs*17 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- FBXO21 | c.431_432del p.F144* | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- GALR2 | c.203dup p.V69Rfs*317 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- GNAZ | c.612del p.Q205Rfs*29 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- GPR75 | c.597del p.A202Pfs*23 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- GRHL1 | c.924del p.F308Lfs*11 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- HAX1 | c.72del p.F24Lfs*4 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- HERC1 | c.13153del p.Q4385Sfs*5 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- IGHV3-13 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- IGHV3-35 | c.83del p.G28Efs*10 | Frame Shift Del (DEL) | VAF 72/183 reads (39%) | called by mutect2, pindel, varscan2
- IL17RB | c.833del p.F278Sfs*34 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- IL1R2 | c.696del p.E233Kfs*6 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- KANK1 | c.593del p.S198Ffs*47 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- KCNJ12 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- KCTD20 | c.947del p.N316Tfs*64 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by pindel, varscan2
- KDM4B | c.395_398del p.I132Tfs*40 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- KIAA0319 | c.2353del p.V785Cfs*36 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- KIF21B | c.271del p.A91Pfs*110 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, varscan2
- KMT2B | c.1304del p.P435Qfs*40 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel
- LDB3 | c.1341del p.S448Hfs*44 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- LINGO4 | c.1578del p.L527Wfs*21 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- LMBRD1 | c.157del p.S53Lfs*2 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- LRRTM3 | c.1603del p.V535Cfs*24 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- MAGEL2 | c.2899dup p.L967Pfs*17 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- MAOB | c.35del p.G12Afs*17 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- MAP1B | c.5901del p.E1968Kfs*2 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- MFHAS1 | c.2293del p.E765Kfs*77 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- MICU2 | c.1043-3del | Splice Region (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- MMP14 | c.25del p.R9Vfs*68 | Frame Shift Del (DEL) | VAF 8/103 reads (8%) | called by mutect2, pindel
- MRPL24 | c.77del p.P26Qfs*40 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- MYO7B | c.3876del p.W1293Gfs*135 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- NCOA2 | c.2234T>C p.L745P | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NF1 | c.4076dup p.Q1360Sfs*20 (on ENST00000358273 / NM_001042492.3; = p.Q1360Sfs*14 on NM_000267.3) | Frame Shift Ins (INS) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- NUP188 | c.180del p.V61* | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- OR2T33 | c.842dup p.L282Ffs*13 | Frame Shift Ins (INS) | VAF 37/134 reads (28%) | called by mutect2, pindel, varscan2
- OR4F17 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.227); called by mutect2, varscan2
- OR4Q3 | c.215del p.L72* | Frame Shift Del (DEL) | VAF 30/151 reads (20%) | called by mutect2, pindel, varscan2
- PACSIN1 | c.832del p.A278Lfs*20 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- PDSS1 | c.605del p.K202Rfs*9 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- PEAR1 | c.755del p.P252Lfs*125 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- PI4K2B | c.1435del p.S479Pfs*40 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- PLG | c.1586del p.N529Ifs*10 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- PLSCR3 | c.725del p.G242Afs*23 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- POLR2A | c.1585del p.Q529Rfs*32 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- PPP4R1 | c.2688del p.D897Tfs*47 (on ENST00000400556 / NM_001042388.3; = p.D880Tfs*47 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | called by mutect2, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- PTCH2 | c.2315del p.P772Hfs*68 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- RABGGTA | c.479del p.P160Lfs*5 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- RTN3 | c.1925del p.N642Mfs*5 (on ENST00000377819 / NM_001265589.2; = p.N623Mfs*5 on NM_201428.3) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- SAG | c.719_721del p.K240del | In Frame Del (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- SAP130 | c.1725del p.I576Lfs*152 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- SCAF4 | c.252del p.F84Lfs*9 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- SDHC | c.423del p.G142Afs*2 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- SDK1 | c.2966dup p.V990Gfs*106 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SH3KBP1 | c.1720del p.L574Cfs*39 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | called by mutect2, pindel, varscan2
- SLAIN1 | c.930del p.T312Hfs*96 (on ENST00000466548; = p.T49Hfs*96 on NM_144595.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.77del p.P26Lfs*2 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 21/45 reads (47%) | called by mutect2, varscan2
- SON | c.2631_2660del p.G889_S898del | In Frame Del (DEL) | VAF 34/95 reads (36%) | called by mutect2, varscan2
- SPATS2L | c.1648_1649del p.V551Pfs*10 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by pindel, varscan2
- SPRY4 | c.520del p.R174Gfs*85 (on ENST00000434127 / NM_001127496.3; = p.R197Gfs*85 on NM_030964.4) | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- STAT2 | c.1467del p.K490Rfs*28 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, pindel, varscan2
- SUGP2 | c.763del p.I255Yfs*4 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, varscan2
- SYDE1 | c.262del p.A88Pfs*9 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- TAB2 | c.1670del p.K557Sfs*5 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- TLN1 | c.4883del p.P1628Rfs*20 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- TMCC1 | c.1550_1551del p.E517Afs*5 (on ENST00000393238 / NM_001349268.2; = p.E193Afs*5 on NM_015008.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- TNC | c.5731del p.R1911Gfs*35 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- TRGV2 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIP6 | c.260del p.G87Afs*11 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- TRMT44 | c.2245del p.R749Gfs*56 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.1637del p.G546Afs*14 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- TUBGCP2 | c.2647del p.Q883Kfs*25 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- UNC79 | c.2535del p.S846Pfs*33 (on ENST00000393151 / NM_001346218.2; = p.S669Pfs*33 on NM_020818.5) | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- VPS54 | c.1332del p.Q446Sfs*20 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- WAS | c.16dup p.M6Nfs*32 | Frame Shift Ins (INS) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- WBP4 | c.363del p.D122Ifs*8 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- WDHD1 | c.3326del p.K1109Sfs*5 | Frame Shift Del (DEL) | VAF 37/91 reads (41%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.7201dup p.T2401Nfs*14 | Frame Shift Ins (INS) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- ZNF292 | c.4026del p.V1343Lfs*83 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ZNF468 | c.309_311del p.E103del | In Frame Del (DEL) | VAF 36/120 reads (30%) | called by pindel, varscan2
- ZNF549 | c.1291del p.R431Dfs*206 (on ENST00000376233 / NM_001199295.2; = p.R418Dfs*206 on NM_153263.2) | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- ZNF746 | c.1344dup p.G449Rfs*96 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- ABCD3 | c.999C>T p.V333= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs748814323, COSV64645244; called by muse, mutect2, varscan2
- ABHD12 | c.1086G>A p.V362= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1204717697, COSV99405558; called by muse, mutect2, varscan2
- ACSF3 | c.270C>T p.G90= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs201113468, COSV58081196; called by muse, mutect2, varscan2
- ACYP2 | c.225C>T p.R75= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100336956; called by muse, mutect2, varscan2
- ADAMTS7 | c.4530G>A p.P1510= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs772623491, COSV101183313; called by muse, mutect2, varscan2
- ADH7 | c.240T>C p.H80= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV99265509; called by muse, mutect2, varscan2
- ALG1L | c.24G>A p.E8= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100444918; called by muse, mutect2, varscan2
- AMPH | c.813G>A p.P271= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1340770895, COSV57738953; called by muse, mutect2, varscan2
- ANK2 | c.10518A>G p.E3506= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs942531992, COSV100004715; called by muse, mutect2, varscan2
- ANK3 | c.555C>T p.H185= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs370456295; called by muse, mutect2, varscan2
- ARFGEF3 | c.2586C>T p.R862= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV99294977; called by muse, mutect2, varscan2
- ARHGAP45 | c.1938G>A p.T646= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1421235430, COSV57433073; called by muse, varscan2
- ARHGEF12 | c.2259T>C p.S753= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100755287; called by muse, mutect2, varscan2
193 further variants in this file (0 protein-altering or splice-affecting, 179 silent, 14 other) are not listed here.
